Somatic mutation profile of tumor specimen TCGA-13-2071-01A (aliquot TCGA-13-2071-01A-02D-1526-09) from TCGA case TCGA-13-2071, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.0 years (23,367 days).
Specimen TCGA-13-2071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff1ce206-5e39-4fda-a3af-dd3d91e788db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-2071-10A (Blood Derived Normal), aliquot TCGA-13-2071-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35c5cc90-cd7f-4ee1-bf9d-7abdba8c254e

The open-access MAF lists 69 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 16, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, Splice Region 2, Splice Site 2, 5'Flank 1, 3'UTR 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.463_468del p.T155_R156del | In Frame Del (DEL) | VAF 56/112 reads (50%) | hotspot (GDC flag); catalogued as rs1555526166; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ADAM2 | c.1967T>C p.I656T | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1014578269, COSV55864034; called by muse, mutect2, varscan2
- AMOT | c.2989G>T p.A997S (on ENST00000371959 / NM_001113490.1; = p.A588S on NM_133265.3) | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV100494778, COSV59064912; called by muse, mutect2, varscan2
- C1orf116 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs746322010, COSV63944239, COSV63944254; called by muse, mutect2, varscan2
- CHD2 | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.971); catalogued as COSV59120867, COSV59122879; called by mutect2, varscan2
- COL5A1 | c.276T>G p.P92= | Splice Region (SNP) | VAF 74/285 reads (26%) | catalogued as COSV65670581; called by muse, mutect2, varscan2
- CYP11B2 | c.1072G>C p.A358P | Missense Mutation (SNP) | VAF 124/205 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV59996463; called by muse, mutect2, varscan2
- DMXL2 | c.5855G>A p.W1952* | Nonsense Mutation (SNP) | VAF 44/189 reads (23%) | catalogued as COSV51849029; called by muse, mutect2, varscan2
- DNM2 | c.1966A>G p.I656V (on ENST00000355667 / NM_001005360.3; = p.I652V on NM_004945.3) | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV58964666; called by muse, mutect2, varscan2
- F13A1 | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 14/416 reads (3%) | catalogued as COSV99341990; called by muse, mutect2
- F8 | c.3980C>T p.T1327M | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs200520711, COSV64274888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDPD2 | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV65533295; called by muse, mutect2, varscan2
- GPNMB | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 48/525 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV99326209; called by muse, mutect2
- GRM8 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 31/451 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100280075; called by muse, mutect2
- HAUS4 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV52827599; called by muse, mutect2, varscan2
- ITGB5 | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 94/369 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs763099829, COSV56150153; called by muse, mutect2, varscan2
- ITGB7 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs765293487, COSV57239162; called by muse, mutect2, varscan2
- JPT2 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV99935946; called by muse, mutect2
- KDR | c.1588T>A p.C530S | Missense Mutation (SNP) | VAF 253/488 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55768072; called by muse, mutect2, varscan2
- KEL | c.1611G>T p.W537C | Missense Mutation (SNP) | VAF 130/545 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV62334138, COSV62335809; called by muse, mutect2, varscan2
- LEPR | c.1389A>T p.Q463H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60757516; called by muse, mutect2, varscan2
- LRRC8A | c.1578C>G p.N526K | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.225); catalogued as COSV52186911; called by muse, mutect2, varscan2
- MCF2 | c.2493G>T p.K831N | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.196); catalogued as COSV58487511; called by muse, mutect2, varscan2
- MPHOSPH8 | c.885del p.S295Rfs*20 | Frame Shift Del (DEL) | VAF 63/296 reads (21%) | catalogued as COSV64056122; called by mutect2, pindel, varscan2
- MPIG6B | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV65389836; called by muse, mutect2, varscan2
- MRPL3 | c.935A>G p.K312R | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV53915040; called by muse, mutect2, varscan2
- MTMR6 | c.1775A>T p.D592V | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV67808688; called by muse, mutect2, varscan2
- MTMR6 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 79/335 reads (24%) | catalogued as COSV67808704; called by muse, mutect2, varscan2
- PCDHA2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 80/121 reads (66%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.259); catalogued as COSV65367939, COSV65368049; called by muse, mutect2, varscan2
- PDIA6 | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs950452062, COSV55351488; called by muse, mutect2, varscan2
- PHF21A | c.846C>G p.H282Q (on ENST00000418153 / NM_001101802.3; = p.H283Q on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 269/796 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs1341083993, COSV57655677; called by muse, mutect2, varscan2
- PI4KB | c.363G>C p.Q121H (on ENST00000368873 / NM_001369623.1; = p.Q133H on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as rs760195563, COSV55018806; called by muse, mutect2, varscan2
- PKM | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV58788001; called by muse, mutect2
- POLR2H | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 51/242 reads (21%) | catalogued as COSV55602073, COSV99658778; called by muse, mutect2, varscan2
- PPP1R13L | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV62908856; called by muse, mutect2, varscan2
- RASGRF1 | c.3796C>T p.R1266* | Nonsense Mutation (SNP) | VAF 158/402 reads (39%) | catalogued as rs201240796, COSV67250386; called by muse, mutect2, varscan2
- SHMT1 | c.1162A>T p.T388S | Missense Mutation (SNP) | VAF 194/363 reads (53%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.51); catalogued as COSV57399290; called by muse, varscan2
- SMOC2 | c.1236C>G p.C412W (on ENST00000356284 / NM_001166412.2; = p.C423W on NM_022138.3) | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100634682, COSV62437092; called by muse, mutect2
- SMURF1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 307/780 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371884669; called by muse, mutect2, varscan2
- SNX25 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV99252257; called by muse, mutect2
- TEX15 | c.4525A>C p.T1509P (on ENST00000256246; = p.T1892P on NM_001350162.2) | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV56348249; called by muse, mutect2, varscan2
- TRIM29 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as COSV100531428; called by muse, mutect2
- USP44 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV99311534; called by muse, mutect2
- USP9X | c.186T>A p.D62E | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61071023; called by muse, mutect2, varscan2
- ZDHHC3 | c.744A>T p.G248= (on ENST00000424952 / NM_001135179.2; = p.G276= on NM_016598.3) | Splice Region (SNP) | VAF 176/463 reads (38%) | catalogued as COSV56101670; called by muse, mutect2, varscan2
- ZNF594 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776752247, COSV68385633; called by muse, mutect2, varscan2
- CDC20 | c.348_370del p.W116* | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- LRP2 | c.6842_6879delinsG p.Y2281Wfs*5 | Frame Shift Del (DEL) | VAF 92/175 reads (53%) | called by pindel, varscan2*
- TMEM196 | c.205-21_210del p.X69_splice | Splice Site (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- ABHD2 | c.270G>A p.R90= | Silent (SNP) | VAF 81/250 reads (32%) | catalogued as COSV61774774; called by muse, mutect2, varscan2
- ADAMTSL3 | c.948T>C p.D316= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV54454061; called by muse, mutect2, varscan2
- ATG7 | c.639T>G p.L213= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as COSV100606570; called by muse, mutect2
- CXCR3 | c.363T>A p.S121= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV65462049; called by muse, mutect2, varscan2
- DLGAP2 | c.3120C>T p.R1040= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV70099962; called by muse, varscan2
- FGF21 | c.201G>A p.G67= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as COSV55810649; called by muse, mutect2, varscan2
- FLG | c.10968C>T p.H3656= | Silent (SNP) | VAF 118/902 reads (13%) | called by muse, mutect2
- GALK1 | c.894C>T p.G298= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs372022762; called by muse, varscan2
- GRIN2B | c.1470C>A p.I490= | Silent (SNP) | VAF 177/351 reads (50%) | catalogued as COSV101663049, COSV74206453; called by muse, mutect2, varscan2
- MXD1 | c.42G>A p.E14= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as COSV52480100; called by muse, mutect2, varscan2
- NPY4R | c.792T>C p.N264= | Silent (SNP) | VAF 72/250 reads (29%) | catalogued as COSV65398293; called by muse, mutect2, varscan2
- PADI2 | c.1032A>T p.R344= | Silent (SNP) | VAF 72/391 reads (18%) | catalogued as COSV64946002; called by muse, mutect2, varscan2
- PCDHAC1 | c.279C>T p.C93= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV53852830; called by muse, mutect2, varscan2
- PCDHB9 | c.1569C>T p.A523= | Silent (SNP) | VAF 260/362 reads (72%) | catalogued as rs1554283157, COSV53380463; called by muse, mutect2, varscan2
- RARB | c.778C>T p.L260= (on ENST00000383772 / NM_001290216.2; = p.L253= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 85/284 reads (30%) | catalogued as COSV58068386; called by muse, mutect2, varscan2
- RTL9 | c.3018A>C p.T1006= | Silent (SNP) | VAF 105/222 reads (47%) | catalogued as COSV71825783; called by muse, mutect2, varscan2
- LEKR1 | c.*449T>G | 3'UTR (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100738494; called by muse, mutect2
- PDE4DIP | c.637-7093A>T | Intron (SNP) | VAF 81/214 reads (38%) | catalogued as COSV57702568; called by muse, mutect2, varscan2
- TTN | c.10361-5098_10361-5056del | Intron (DEL) | VAF 43/304 reads (14%) | called by mutect2, pindel
- UTS2 | chr1:7853400 C>T | 5'Flank (SNP) | VAF 56/315 reads (18%) | catalogued as COSV50013133; called by muse, mutect2
